Somatic mutation profile of tumor specimen C3L-07965-01 (aliquot CPT0479600009) from CPTAC case C3L-07965, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIID; Age at diagnosis: 69.4 years (25,349 days).
Specimen C3L-07965-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 553f5bce-f06e-4cd3-b4ae-e4faaaf58823.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07965-31 (Blood Derived Normal), aliquot CPT0479630002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cc9f41b-1d7a-4444-b88c-c34bb1422cb3

The open-access MAF lists 561 somatic variants for this specimen: 353 protein-altering or splice-affecting, 189 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 318, Silent 189, Nonsense Mutation 26, Intron 11, 3'UTR 3, Frame Shift Ins 3, Splice Region 3, RNA 2, 5'Flank 2, Splice Site 2, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/248 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/247 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HBB | c.48G>A p.W16* | Nonsense Mutation (SNP) | VAF 71/280 reads (25%) | catalogued as rs34716011, CM900120; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MMACHC | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 149/453 reads (33%) | catalogued as rs796051995, CM060057; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 80/228 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.061); catalogued as rs773100250, COSV55953508; called by muse, mutect2, varscan2
- ABCC12 | c.2981C>T p.S994F | Missense Mutation (SNP) | VAF 109/398 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as COSV100252534; called by muse, mutect2, varscan2
- ACMSD | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs910294827, COSV99298773; called by muse, mutect2, varscan2
- ACY3 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 81/260 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.75); catalogued as COSV99663137; called by muse, mutect2, varscan2
- ADAM29 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 79/257 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs867060959, COSV63662440; called by muse, mutect2, varscan2
- ADAM7 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 87/331 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as rs1231052704, COSV51538861; called by muse, mutect2, varscan2
- ADCY1 | c.2478G>A p.M826I | Missense Mutation (SNP) | VAF 131/326 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV52040384; called by muse, mutect2, varscan2
- ADCY8 | c.2116C>T p.Q706* | Nonsense Mutation (SNP) | VAF 52/168 reads (31%) | catalogued as COSV53895249; called by muse, mutect2, varscan2
- ADGRG4 | c.3164C>T p.S1055F | Missense Mutation (SNP) | VAF 149/232 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV54966483; called by muse, mutect2, varscan2
- AFF3 | c.35G>A p.W12* | Nonsense Mutation (SNP) | VAF 46/204 reads (23%) | catalogued as rs1278114897; called by muse, mutect2, varscan2
- AGT | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 111/427 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs567719599, COSV100794172; called by muse, mutect2, varscan2
- AHNAK2 | c.1354G>A p.G452S | Missense Mutation (SNP) | VAF 116/402 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0.141); catalogued as rs778199107; called by muse, mutect2, varscan2
- ALOX5 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 160/467 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs1047630934, COSV65550945; called by muse, mutect2, varscan2
- ANO4 | c.827G>A p.G276E (on ENST00000392977 / NM_001286615.2; = p.G241E on NM_178826.4) | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as COSV54612988; called by muse, mutect2, varscan2
- AP2A2 | c.1760C>T p.T587I | Missense Mutation (SNP) | VAF 133/463 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.08); catalogued as rs768024984, COSV100172605; called by muse, mutect2, varscan2
- API5 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101124524; called by muse, mutect2, varscan2
- APOB | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.006); catalogued as COSV51956984; called by muse, mutect2, varscan2
- ARID2 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 95/326 reads (29%) | catalogued as COSV57607234; called by muse, mutect2, varscan2
- ARMC4 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV53463018; called by muse, mutect2
- ART1 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 89/322 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs145061135, COSV99167160; called by muse, mutect2, varscan2
- ATP6V0A4 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 113/267 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs894665573, COSV59474270; called by muse, mutect2, varscan2
- BRINP3 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 93/508 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs199983605, COSV66532306, COSV66534597; called by muse, mutect2, varscan2
- C1orf87 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 98/350 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs762859456, COSV64597005; called by muse, mutect2, varscan2
- CAMK1D | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV66621975; called by muse, mutect2, varscan2
- CAMTA1 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 90/312 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57898064; called by muse, mutect2
- CCKAR | c.1006C>G p.R336G | Missense Mutation (SNP) | VAF 136/448 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55161035; called by muse, mutect2, varscan2
- CCNB3 | c.3655G>A p.E1219K | Missense Mutation (SNP) | VAF 76/129 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52080430; called by muse, mutect2, varscan2
- CDH18 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs370630427; called by muse, mutect2, varscan2
- CDH7 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 81/309 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59883340; called by muse, mutect2, varscan2
- CDK18 | c.23A>G p.N8S | Missense Mutation (SNP) | VAF 89/274 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs779734880; called by muse, mutect2, varscan2
- CFH | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 111/492 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs955234498; called by muse, varscan2
- CHD5 | c.3590C>T p.T1197M | Missense Mutation (SNP) | VAF 81/266 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52428683; called by muse, mutect2, varscan2
- CHST6 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 176/568 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72547538, CM002587, COSV59999984; called by muse, mutect2, varscan2
- COL22A1 | c.1831G>A p.G611R | Missense Mutation (SNP) | VAF 104/337 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57326392; called by muse, mutect2, varscan2
- COL6A6 | c.2858C>T p.P953L | Missense Mutation (SNP) | VAF 109/425 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100650116; called by muse, mutect2, varscan2
- CR2 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 75/303 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65507728; called by muse, mutect2, varscan2
- CROCC2 | c.4174G>A p.A1392T | Missense Mutation (SNP) | VAF 71/275 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as rs1407508589; called by muse, mutect2, varscan2
- CSMD2 | c.3493G>A p.G1165R | Missense Mutation (SNP) | VAF 104/335 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1233185953, COSV99594432; called by muse, mutect2, varscan2
- CTSG | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1189057436, COSV53534982, COSV99361529; called by muse, mutect2, varscan2
- CYTH2 | c.959C>T p.P320L (on ENST00000427476; = p.P319L on NM_004228.7) | Missense Mutation (SNP) | VAF 13/344 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs887535289; called by muse, mutect2
- DACT1 | c.2171C>A p.S724Y | Missense Mutation (SNP) | VAF 141/439 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762646784, COSV60021481; called by muse, mutect2, varscan2
- DAO | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 88/391 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1465408785; called by muse, mutect2, varscan2
- DCC | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 82/314 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.238); catalogued as rs142367900; called by muse, mutect2, varscan2
- DCC | c.2114G>A p.G705E | Missense Mutation (SNP) | VAF 88/286 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs191508830; called by muse, mutect2, varscan2
- DNAH11 | c.3098C>T p.T1033I | Missense Mutation (SNP) | VAF 162/400 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.625); catalogued as rs776389690; called by muse, mutect2
- DNAH12 | c.569A>C p.H190P | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV60857950; called by muse, mutect2, varscan2
- DNAH5 | c.10576G>A p.A3526T | Missense Mutation (SNP) | VAF 84/227 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs868745747, COSV54253123, COSV99448765; called by muse, mutect2, varscan2
- DSG1 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 54/190 reads (28%) | catalogued as rs755271644, COSV99935571; called by muse, mutect2, varscan2
- DSG4 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57399139; called by muse, mutect2, varscan2
- DVL1 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 90/359 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1430413476, COSV66678465; called by muse, mutect2, varscan2
- DYNC1H1 | c.7156C>T p.P2386S | Missense Mutation (SNP) | VAF 127/461 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.139); catalogued as rs1301304334; called by muse, mutect2, varscan2
- EVPL | c.5173G>A p.E1725K | Missense Mutation (SNP) | VAF 133/419 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56915109; called by muse, mutect2, varscan2
- FBN3 | c.4232G>A p.G1411E | Missense Mutation (SNP) | VAF 69/282 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV99561303; called by muse, mutect2, varscan2
- FER1L5 | c.1454C>T p.S485F (on ENST00000623019; = p.S490F on NM_001293083.2) | Missense Mutation (SNP) | VAF 75/244 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70069723; called by muse, mutect2, varscan2
- FLNC | c.3862G>C p.V1288L | Missense Mutation (SNP) | VAF 101/557 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.087); catalogued as rs750415476; called by muse, mutect2, varscan2
- FREM2 | c.3496C>T p.R1166C | Missense Mutation (SNP) | VAF 110/347 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs201063766, COSV54844085; called by muse, mutect2, varscan2
- FRY | c.3427C>T p.R1143C | Missense Mutation (SNP) | VAF 104/327 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs771312453, COSV66568488, COSV66570042; called by muse, mutect2, varscan2
- FYTTD1 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs772495686, COSV54084854; called by muse, mutect2, varscan2
- GABRG1 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs568096519, COSV54949731; called by muse, mutect2, varscan2
- GDF5 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 132/440 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65502004; called by muse, mutect2, varscan2
- GK2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 109/363 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1321996211, COSV62626188; called by muse, mutect2, varscan2
- GRIK3 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 115/418 reads (28%) | catalogued as COSV66144907; called by muse, mutect2, varscan2
- GRIN3A | c.2090G>A p.W697* | Nonsense Mutation (SNP) | VAF 139/283 reads (49%) | catalogued as COSV62458184; called by muse, mutect2, varscan2
- GRM6 | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as rs865820370, COSV51433461; called by muse, mutect2
- GSTM5 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99859545; called by muse, mutect2, varscan2
- GTPBP3 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 119/356 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as rs376384130; called by muse, mutect2, varscan2
- HCRTR2 | c.1309G>A p.G437R | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.999); catalogued as COSV100904704; called by muse, mutect2, varscan2
- HEMGN | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 109/248 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as rs1451210817, COSV52326091; called by muse, mutect2, varscan2
- HHIP | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 91/268 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs369873424; called by muse, mutect2, varscan2
- HRNR | c.6518G>A p.G2173D | Missense Mutation (SNP) | VAF 124/2514 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs775390062; called by muse, mutect2
- HRNR | c.5108G>A p.G1703D | Missense Mutation (SNP) | VAF 185/1881 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as rs769298318, COSV64261429; called by muse, mutect2, varscan2
- IGKV3-20 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 83/412 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs373812042; called by muse, mutect2, varscan2
- IL17C | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 116/464 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs200412244; called by muse, mutect2, varscan2
- ILDR1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 127/497 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759748774, COSV56548375; called by muse, mutect2, varscan2
- ILDR2 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 78/460 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1360794311, COSV99613269; called by muse, mutect2, varscan2
- IRX2 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57410611; called by muse, mutect2, varscan2
- ITIH1 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 96/349 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs768997090, COSV99835179; called by muse, mutect2, varscan2
- ITLN1 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 105/552 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs1360767242; called by muse, mutect2, varscan2
- JPH2 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 155/439 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as rs745760392; called by muse, mutect2, varscan2
- KDM3B | c.4784C>T p.A1595V | Missense Mutation (SNP) | VAF 82/170 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as rs868777969; called by muse, mutect2, varscan2
- KIAA1217 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64609044; called by muse, mutect2
- KIR3DL3 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 191/652 reads (29%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.954); catalogued as COSV99399748; called by muse, mutect2
- LRFN2 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 137/417 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs959343309, COSV57823890; called by muse, mutect2, varscan2
- LRRC9 | c.4313G>A p.C1438Y (on ENST00000445360; = p.M1494I on NM_001355272.2) | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs563029514; called by muse, mutect2, varscan2
- MAGEB6B | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 91/164 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.701); catalogued as COSV101301707; called by muse, mutect2, varscan2
- MAGEC1 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 122/236 reads (52%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.641); catalogued as COSV53581572; called by muse, mutect2, varscan2
- MAP2K1 | c.179T>G p.V60G | Missense Mutation (SNP) | VAF 103/341 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as rs730880501, CM147586, COSV61068773; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MBP | c.835G>A p.D279N (on ENST00000355994 / NM_001025101.2; = p.D161N on NM_002385.3) | Missense Mutation (SNP) | VAF 83/238 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.858); catalogued as rs1337832380, COSV62828920; called by muse, mutect2, varscan2
- MCF2 | c.2057G>A p.G686E | Missense Mutation (SNP) | VAF 69/110 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV58480481; called by muse, mutect2, varscan2
- MLLT6 | c.2503C>T p.P835S | Missense Mutation (SNP) | VAF 134/498 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.647); catalogued as rs962810287; called by muse, mutect2, varscan2
- MLXIP | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 114/346 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59837894; called by muse, mutect2, varscan2
- MMRN2 | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 59/439 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.321); catalogued as rs371708539; called by muse, mutect2, varscan2
- MNDA | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 74/465 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772250204; called by muse, mutect2, varscan2
- MUC16 | c.20343G>A p.M6781I | Missense Mutation (SNP) | VAF 99/349 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.037); catalogued as rs771752432, COSV101199297; called by muse, mutect2, varscan2
- MUC16 | c.9169C>T p.L3057F | Missense Mutation (SNP) | VAF 72/247 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs771499362, COSV67448509; called by muse, mutect2, varscan2
- MYH8 | c.4609G>A p.E1537K | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1306298843; called by muse, mutect2, varscan2
- MYH8 | c.4279G>A p.E1427K | Missense Mutation (SNP) | VAF 82/333 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV67965376; called by muse, mutect2, varscan2
- MYL7 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 72/395 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as rs769613669; called by muse, mutect2, varscan2
- MYO5B | c.4535C>G p.A1512G | Missense Mutation (SNP) | VAF 106/347 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV53215275; called by muse, mutect2, varscan2
- NALCN | c.357G>A p.W119* | Nonsense Mutation (SNP) | VAF 49/187 reads (26%) | catalogued as COSV51924549; called by muse, mutect2, varscan2
- NEBL | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 86/242 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.151); catalogued as rs774294999, COSV65802298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NGF | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 92/378 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs566033399, COSV65689105; called by muse, mutect2, varscan2
- NLRP13 | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 125/446 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.088); catalogued as rs368799385; called by muse, mutect2
- NRG3 | c.1892C>T p.A631V (on ENST00000404547 / NM_001370084.1; = p.A607V on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.055); catalogued as rs1564696990; called by muse, mutect2
- NSA2 | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV57188291; called by muse, mutect2, varscan2
- NYNRIN | c.3575C>T p.P1192L | Missense Mutation (SNP) | VAF 123/481 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.255); catalogued as rs751558441; called by muse, mutect2, varscan2
- OR10G9 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 102/395 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV66686529; called by muse, mutect2, varscan2
- OR10J5 | c.262C>T p.H88Y | Missense Mutation (SNP) | VAF 123/580 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58385072; called by muse, mutect2, varscan2
- OR1I1 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 137/444 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV52919076; called by muse, mutect2, varscan2
- OR2Z1 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV60691984, COSV60692689; called by muse, mutect2, varscan2
- OR4C5 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 100/325 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as rs73460777; called by muse, mutect2, varscan2
- OR51A4 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 118/418 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.361); catalogued as COSV66749600; called by muse, varscan2
- OR51Q1 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 66/309 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV56180004; called by muse, mutect2
- OR5T1 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 90/345 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1249627332, COSV57301738; called by muse, mutect2, varscan2
- OR5T2 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 110/379 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV57587719; called by muse, mutect2, varscan2
- PAPPA2 | c.4097C>T p.S1366L | Missense Mutation (SNP) | VAF 326/488 reads (67%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs773829570, COSV62801601; called by muse, mutect2, varscan2
- PARM1 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367804546; called by muse, mutect2, varscan2
- PARVG | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 73/266 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); catalogued as rs372422010; called by muse, mutect2, varscan2
- PCDHB8 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 117/386 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV50756296; called by muse, mutect2, varscan2
- PDPN | c.470C>T p.S157L (on ENST00000621990; = p.S233L on NM_006474.4) | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142964620; called by muse, mutect2, varscan2
- PENK | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 123/391 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs757026631; called by muse, mutect2, varscan2
- PIK3R6 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 94/281 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768662610; called by muse, mutect2, varscan2
- PKHD1L1 | c.401G>A p.W134* | Nonsense Mutation (SNP) | VAF 33/279 reads (12%) | catalogued as rs762322776; called by muse, mutect2, varscan2
- PLA2G1B | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 84/366 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369316608; called by muse, mutect2, varscan2
- PLEC | c.2197C>T p.R733W (on ENST00000322810 / NM_201380.4; = p.R623W on NM_000445.5) | Missense Mutation (SNP) | VAF 89/366 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs556691235; ClinVar: uncertain significance; called by muse, varscan2
- PLXDC2 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.289); catalogued as rs540394643, COSV65909263; called by muse, mutect2, varscan2
- PPIAL4G | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 492/943 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.798); catalogued as rs1191612559, COSV70087275; called by muse, mutect2, varscan2
- PROM2 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 98/379 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.059); catalogued as COSV58297150; called by muse, mutect2, varscan2
- PSG8 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 136/482 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV60614372; called by muse, mutect2, varscan2
- PTPRQ | c.4534C>T p.R1512C (on ENST00000616559; = p.R1470C on NM_001145026.2) | Missense Mutation (SNP) | VAF 90/303 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs769414150, COSV57044324; called by muse, mutect2, varscan2
- RAB23 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as COSV58098958; called by muse, varscan2
- RAB44 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 70/250 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs1562062699; called by muse, mutect2, varscan2
- RBM14 | c.365A>G p.E122G | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs745868557; called by muse, mutect2, varscan2
- RHCG | c.1139G>A p.G380D | Missense Mutation (SNP) | VAF 75/263 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV51515260; called by muse, mutect2, varscan2
- ROBO2 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 87/292 reads (30%) | SIFT tolerated (0.99); PolyPhen benign (0.048); catalogued as COSV59919865; called by muse, mutect2, varscan2
- RP1L1 | c.3737G>A p.S1246N | Missense Mutation (SNP) | VAF 121/373 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778777831; called by muse, mutect2, varscan2
- RPS6KA6 | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 105/163 reads (64%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as COSV104392997, COSV53129606; called by muse, mutect2, varscan2
- RUFY4 | c.1129C>T p.L377F | Missense Mutation (SNP) | VAF 110/381 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.08); catalogued as rs1249096243; called by muse, mutect2, varscan2
- RUNDC3B | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 199/474 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as rs1173051243, COSV56692938; called by muse, mutect2, varscan2
- RYR3 | c.4018C>T p.P1340S | Missense Mutation (SNP) | VAF 97/318 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV66779483; called by muse, mutect2, varscan2
- S1PR4 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 161/540 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as rs767058179; called by muse, mutect2, varscan2
- SCN11A | c.4033C>T p.Q1345* | Nonsense Mutation (SNP) | VAF 52/227 reads (23%) | catalogued as rs751009800; called by muse, mutect2, varscan2
- SCN5A | c.5956G>A p.D1986N (on ENST00000333535 / NM_198056.3; = p.D1985N on NM_000335.5) | Missense Mutation (SNP) | VAF 130/370 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs756562718, COSV61115651; called by muse, mutect2, varscan2
- SCN7A | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV69268884; called by muse, mutect2, varscan2
- SERPINI1 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as COSV99854821; called by muse, mutect2, varscan2
- SHANK1 | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs267605596, COSV53263641; called by muse, mutect2, varscan2
- SHANK2 | c.3545C>T p.P1182L | Missense Mutation (SNP) | VAF 155/451 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); catalogued as COSV99574165; called by muse, mutect2, varscan2
- SHANK2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as rs1555100977; called by muse, mutect2, varscan2
- SIGLEC6 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 120/419 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1224241402, COSV58434515; called by muse, mutect2, varscan2
- SLC24A4 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 93/319 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as rs768431791; called by muse, mutect2, varscan2
- SLC9B1 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56467425; called by muse, mutect2, varscan2
- SMG5 | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 90/603 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.082); catalogued as rs1245185769, COSV62433935; called by muse, mutect2, varscan2
- SPAG17 | c.2836C>T p.R946* | Nonsense Mutation (SNP) | VAF 84/296 reads (28%) | catalogued as rs201253941, COSV60463148, COSV60465006; called by muse, mutect2, varscan2
- SRD5A2 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51871666; called by muse, mutect2, varscan2
- STAB2 | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 116/346 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs184975337; called by muse, mutect2, varscan2
- STARD7 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61525455; called by muse, mutect2, varscan2
- STK17B | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772810962, COSV55830202; called by muse, mutect2, varscan2
- SULT2A1 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 75/272 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1453723177; called by muse, mutect2, varscan2
- SYNE1 | c.7756G>A p.E2586K (on ENST00000367255 / NM_182961.4; = p.E2593K on NM_033071.3) | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776873775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TENM3 | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs372715753; called by muse, mutect2, varscan2
- TEX15 | c.2888G>A p.R963Q (on ENST00000256246; = p.R1346Q on NM_001350162.2) | Missense Mutation (SNP) | VAF 65/254 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.808); catalogued as rs776973308, COSV56342158; called by muse, mutect2, varscan2
- TLL1 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 57/208 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1452918005, COSV50269380; called by muse, mutect2, varscan2
- TLR8 | c.166G>A p.E56K (on ENST00000218032 / NM_138636.5; = p.E74K on NM_016610.4) | Missense Mutation (SNP) | VAF 137/239 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.424); catalogued as COSV54319986; called by muse, mutect2, varscan2
- TMCO1 | c.178C>G p.L60V (on ENST00000612311 / NM_001256164.1; = p.L9V on NM_019026.6) | Missense Mutation (SNP) | VAF 88/456 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs745557634; called by muse, mutect2, varscan2
- TMPRSS11F | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 121/360 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs749629232, COSV62465557; called by muse, mutect2, varscan2
- TMPRSS7 | c.2218G>A p.E740K (on ENST00000452346; = p.E614K on NM_001042575.2) | Missense Mutation (SNP) | VAF 50/239 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769766642; called by muse, mutect2, varscan2
- TNIP3 | c.88A>G p.K30E | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50246059; called by muse, mutect2, varscan2
- TPTE | c.185G>A p.R62Q (on ENST00000618007 / NM_199261.4; = p.R44Q on NM_199259.4) | Missense Mutation (SNP) | VAF 61/412 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs578173995; called by muse, mutect2, varscan2
- TRAV4 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 64/227 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs535279911; called by muse, mutect2, varscan2
- TRBV6-1 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 43/345 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1021645630; called by muse, mutect2, varscan2
- TRIM48 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.343); catalogued as COSV70161583; called by muse, mutect2, varscan2
- TRIM60 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 95/335 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.022); catalogued as rs535129175, COSV61969990, COSV61971708; called by muse, mutect2, varscan2
- TRPC5 | c.1326G>A p.M442I | Missense Mutation (SNP) | VAF 92/167 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.89); catalogued as COSV53298495; called by muse, mutect2, varscan2
- TRRAP | c.3788C>T p.S1263L | Missense Mutation (SNP) | VAF 122/503 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as rs782296505; called by muse, mutect2, varscan2
- TSKS | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 115/355 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs746282153, COSV55874188; called by muse, mutect2, varscan2
- TTN | c.33685G>A p.E11229K (on ENST00000591111; = p.E10302K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/183 reads (28%) | PolyPhen benign (0.009); catalogued as COSV59986216; called by muse, mutect2, varscan2
- TTN | c.17482G>A p.E5828K (on ENST00000591111; = p.E4901K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/467 reads (26%) | PolyPhen possibly damaging (0.54); catalogued as rs267599065, COSV60006328; called by muse, mutect2, varscan2
- UBA6 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100451592; called by mutect2, varscan2
- UBQLN3 | c.1789C>T p.H597Y | Missense Mutation (SNP) | VAF 94/314 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV61164202; called by muse, mutect2, varscan2
- UNC13C | c.4429G>A p.E1477K | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.985); catalogued as rs1369385841, COSV52907755; called by muse, mutect2, varscan2
- USP13 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1416943181; called by muse, mutect2, varscan2
- USP17L4 | c.1425G>A p.M475I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.046); catalogued as rs913098129; called by mutect2, varscan2
- VSIR | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 83/317 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs1357026078; called by muse, mutect2, varscan2
- VSIR | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 80/310 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV99819028; called by muse, mutect2, varscan2
- VSTM1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 128/389 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.792); catalogued as COSV58075521; called by muse, mutect2, varscan2
- WDFY4 | c.1402C>T p.R468* | Nonsense Mutation (SNP) | VAF 122/306 reads (40%) | catalogued as rs539358549, COSV57438234; called by muse, mutect2, varscan2
- WDFY4 | c.5314G>A p.E1772K | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as COSV57453994; called by muse, mutect2, varscan2
- WNK1 | c.2835C>T p.G945= | Splice Region (SNP) | VAF 52/172 reads (30%) | catalogued as rs767531047; called by muse, mutect2, varscan2
- XRCC6 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.061); catalogued as COSV63752494; called by muse, mutect2, varscan2
- ZNF479 | c.125G>A p.R42K | Missense Mutation (SNP) | VAF 26/373 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV58638268; called by muse, mutect2
- ZNF627 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs1193768469, COSV63142224; called by muse, mutect2, varscan2
- ZNF729 | c.3031A>T p.K1011* | Nonsense Mutation (SNP) | VAF 83/288 reads (29%) | catalogued as COSV62604860; called by muse, mutect2, varscan2
- ZNF772 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 135/444 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as rs776882068; called by muse, mutect2, varscan2
- ZNF98 | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 90/330 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.305); catalogued as rs1334732549; called by muse, mutect2, varscan2
- ABCA13 | c.14053G>A p.G4685S | Missense Mutation (SNP) | VAF 97/224 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ABCA8 | c.4346C>T p.A1449V | Missense Mutation (SNP) | VAF 74/277 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ABHD10 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- ACAN | c.4247G>A p.G1416E | Missense Mutation (SNP) | VAF 95/497 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ACY3 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ADAM7 | c.1508A>T p.K503I | Missense Mutation (SNP) | VAF 84/298 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- ADAMTS18 | c.1785G>A p.W595* | Nonsense Mutation (SNP) | VAF 101/362 reads (28%) | called by muse, mutect2, varscan2
- ADAMTS18 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 137/391 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ADGRV1 | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 44/259 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ADGRV1 | c.1569G>A p.M523I | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP13 | c.2284C>T p.P762S | Missense Mutation (SNP) | VAF 130/402 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- AKAP6 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANK3 | c.10939G>A p.G3647R | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ANKRD11 | c.743A>C p.K248T | Missense Mutation (SNP) | VAF 147/492 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- APBB1IP | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.145); called by muse, mutect2
- ARAP2 | c.2812A>T p.K938* | Nonsense Mutation (SNP) | VAF 64/222 reads (29%) | called by muse, mutect2, varscan2
- ASXL3 | c.3055A>G p.I1019V | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ATXN1 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 131/374 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- BANK1 | c.2069G>A p.G690E | Missense Mutation (SNP) | VAF 104/344 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BEND2 | c.1429+1G>A p.X477_splice | Splice Site (SNP) | VAF 81/131 reads (62%) | called by muse, mutect2, varscan2
- C10orf71 | c.3835G>A p.D1279N | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- C2orf78 | c.1815G>A p.M605I | Missense Mutation (SNP) | VAF 113/408 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- CAD | c.2007T>G p.Y669* | Nonsense Mutation (SNP) | VAF 58/267 reads (22%) | called by muse, mutect2, varscan2
- CAMTA1 | c.416A>C p.K139T | Missense Mutation (SNP) | VAF 90/306 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CAPZA2 | c.660T>C p.N220= | Splice Region (SNP) | VAF 20/129 reads (16%) | called by muse, mutect2, varscan2
- CASR | c.1996C>T p.L666F (on ENST00000490131; = p.L743F on NM_000388.4) | Missense Mutation (SNP) | VAF 98/356 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC69 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDH18 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CFH | c.2800C>T p.P934S | Missense Mutation (SNP) | VAF 180/258 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CNGA1 | c.370A>C p.K124Q | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- CNTN6 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CROCC2 | c.4173G>A p.M1391I | Missense Mutation (SNP) | VAF 69/272 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DHX8 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 81/361 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- DMBT1 | c.2186C>T p.S729F | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- DMD | c.8675C>T p.P2892L | Missense Mutation (SNP) | VAF 85/140 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DMTN | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 98/370 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- DOC2B | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 131/435 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DSC3 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 104/343 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EBF4 | c.616C>T p.P206S (on ENST00000609451; = p.P202S on NM_001110514.1) | Missense Mutation (SNP) | VAF 95/371 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ELF3 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 144/244 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- EMB | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- EPRS1 | c.1616T>C p.V539A | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- ERFL | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 104/318 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- F9 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- FAM160A1 | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 118/401 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FAM178B | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 144/522 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- FAM227B | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FAT1 | c.9508G>A p.G3170R | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FGA | c.1313G>A p.G438E | Missense Mutation (SNP) | VAF 88/317 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLNC | c.7853C>T p.S2618F | Missense Mutation (SNP) | VAF 265/583 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- FLT1 | c.2525T>C p.V842A | Missense Mutation (SNP) | VAF 110/343 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- FPR2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 68/276 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FRAS1 | c.3080T>G p.L1027R | Missense Mutation (SNP) | VAF 101/369 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GABARAPL1 | c.205del p.H69Tfs*2 | Frame Shift Del (DEL) | VAF 81/377 reads (21%) | called by mutect2, pindel, varscan2
- GABRE | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 111/174 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLT8D2 | c.1040A>T p.H347L | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GLUL | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 97/465 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GMPPB | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GRM3 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 122/516 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL27RA | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 109/380 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- IL37 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 114/323 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- INHBB | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 149/499 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- IPO4 | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 95/308 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ITGA8 | c.2862G>A p.W954* | Nonsense Mutation (SNP) | VAF 57/188 reads (30%) | called by muse, mutect2, varscan2
- ITIH3 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 91/287 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KBTBD2 | c.595dup p.M199Nfs*7 | Frame Shift Ins (INS) | VAF 167/460 reads (36%) | called by mutect2, pindel, varscan2
- KPRP | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 345/657 reads (53%) | called by muse, mutect2, varscan2
- KRTAP19-2 | c.134G>T p.R45I | Missense Mutation (SNP) | VAF 85/300 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- LOXHD1 | c.3919C>T p.P1307S | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRBA | c.7687C>T p.Q2563* | Nonsense Mutation (SNP) | VAF 83/326 reads (25%) | called by muse, mutect2, varscan2
- LRP2 | c.13189C>T p.P4397S | Missense Mutation (SNP) | VAF 76/269 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC14B | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 118/457 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- LRRC9 | c.3539G>A p.G1180E | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- LRRIQ4 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LTBP1 | c.1159G>A p.G387S (on ENST00000404816 / NM_206943.4; = p.G61S on NM_000627.4) | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MBD3L3 | c.409A>C p.S137R | Missense Mutation (SNP) | VAF 149/1382 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MCPH1 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 182/424 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MGAM2 | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC20 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 126/425 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MUC22 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 363/601 reads (60%) | SIFT tolerated, low confidence (0.57); called by muse, mutect2, varscan2
- MYBPH | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 238/396 reads (60%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MYOCD | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 82/330 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- NLRP1 | c.3901G>A p.E1301K | Missense Mutation (SNP) | VAF 76/282 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- NLRP5 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 129/426 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOM1 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 153/602 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NPAS3 | c.2308G>A p.G770S (on ENST00000356141 / NM_001164749.2; = p.G738S on NM_022123.3) | Missense Mutation (SNP) | VAF 148/457 reads (32%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPHP3 | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 94/310 reads (30%) | called by muse, mutect2, varscan2
- NPIPB15 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 73/481 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- OBSCN | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR10G6 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 88/305 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- OR1Q1 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 120/288 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OR4E1 | c.894G>A p.M298I | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR4F4 | c.787T>A p.F263I | Missense Mutation (SNP) | VAF 88/409 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR51E2 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 115/376 reads (31%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR5D13 | c.58dup p.S20Ffs*47 | Frame Shift Ins (INS) | VAF 106/433 reads (24%) | called by mutect2, pindel, varscan2
- PCDH18 | c.2959G>A p.G987R | Missense Mutation (SNP) | VAF 104/403 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCGF5 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- PDE1C | c.1548C>G p.I516M | Missense Mutation (SNP) | VAF 180/397 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PIK3C2G | c.2020G>A p.E674K (on ENST00000676171; = p.E633K on NM_004570.5) | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PIK3IP1 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 105/385 reads (27%) | called by muse, mutect2, varscan2
- PKD2 | c.2014C>T p.L672F | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP4R3A | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 79/283 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- PROM2 | c.1006C>G p.L336V | Missense Mutation (SNP) | VAF 110/376 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- PRPF8 | c.5674C>T p.P1892S | Missense Mutation (SNP) | VAF 154/497 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRSS35 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 127/287 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTK2B | c.2722G>A p.V908M | Missense Mutation (SNP) | VAF 71/247 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PTPRB | c.4495G>A p.D1499N | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PTPRT | c.3390G>A p.E1130= | Splice Region (SNP) | VAF 73/242 reads (30%) | called by muse, mutect2, varscan2
- PXMP4 | c.434A>C p.K145T | Missense Mutation (SNP) | VAF 127/417 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- QTRT1 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 106/344 reads (31%) | called by muse, varscan2
- RFX7 | c.2918G>T p.S973I (on ENST00000559447 / NM_001368074.1; = p.S1070I on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/310 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- RHBDL1 | c.536C>T p.P179L (on ENST00000219551 / NM_001318733.2; = p.P114L on NM_001278720.2) | Missense Mutation (SNP) | VAF 124/410 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RP1 | c.6142G>A p.D2048N | Missense Mutation (SNP) | VAF 94/302 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RPAP1 | c.1613G>A p.G538E | Missense Mutation (SNP) | VAF 80/273 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SALL4 | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 122/445 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SEC22C | c.296A>G p.D99G | Missense Mutation (SNP) | VAF 102/313 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- SEMA5A | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SEZ6 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 167/545 reads (31%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.4780C>T p.H1594Y | Missense Mutation (SNP) | VAF 134/510 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC13A4 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 170/408 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- SLC25A12 | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- SLC40A1 | c.1410G>A p.W470* | Nonsense Mutation (SNP) | VAF 38/166 reads (23%) | called by muse, mutect2, varscan2
- SMYD4 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 111/427 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNX19 | c.2939A>T p.D980V | Missense Mutation (SNP) | VAF 80/296 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ST6GAL1 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 122/369 reads (33%) | PolyPhen benign (0.317); called by muse, mutect2, varscan2
- ST8SIA4 | c.653T>G p.L218R | Missense Mutation (SNP) | VAF 81/299 reads (27%) | PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- STPG3 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 170/517 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYCP1 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TCF4 | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 104/322 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TDO2 | c.100A>G p.R34G | Missense Mutation (SNP) | VAF 109/327 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TDRD15 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TLE3 | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 94/317 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- TMEM61 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 170/541 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- TMTC2 | c.644C>A p.T215N | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TRANK1 | c.6814G>A p.E2272K | Missense Mutation (SNP) | VAF 115/345 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRHDE | c.2131-1G>A p.X711_splice | Splice Site (SNP) | VAF 69/265 reads (26%) | called by muse, mutect2, varscan2
- TRIM49B | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TRIM64B | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 81/579 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- TRIP13 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 74/245 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VPS13B | c.8102C>A p.T2701K | Missense Mutation (SNP) | VAF 118/325 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- WDFY2 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 61/232 reads (26%) | called by muse, mutect2, varscan2
- WDFY4 | c.5872C>T p.L1958F | Missense Mutation (SNP) | VAF 33/367 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.601); called by muse, mutect2
- WDFY4 | c.5873T>A p.L1958H | Missense Mutation (SNP) | VAF 33/370 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- WDR7 | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 116/373 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR87 | c.3704C>T p.T1235I | Missense Mutation (SNP) | VAF 96/372 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ZBTB22 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 129/422 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- ZCCHC7 | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZDBF2 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 67/246 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZMAT4 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZMIZ2 | c.2186C>T p.P729L | Missense Mutation (SNP) | VAF 92/353 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ZNF37A | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF728 | c.1168C>T p.H390Y | Missense Mutation (SNP) | VAF 82/320 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF790 | c.272dup p.N91Kfs*5 | Frame Shift Ins (INS) | VAF 50/134 reads (37%) | called by mutect2, varscan2
- ZNF813 | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 99/379 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZWILCH | c.1382T>C p.V461A | Missense Mutation (SNP) | VAF 75/261 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCC11 | c.1326G>A p.T442= | Silent (SNP) | VAF 62/247 reads (25%) | catalogued as rs935505934, COSV62321436; called by muse, mutect2, varscan2
- ABCC3 | c.831G>A p.G277= | Silent (SNP) | VAF 110/372 reads (30%) | catalogued as COSV53327288; called by muse, mutect2, varscan2
- AC092143.1 | c.2064C>T p.F688= | Silent (SNP) | VAF 165/545 reads (30%) | catalogued as rs749945164, COSV59247855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADARB1 | c.426C>T p.F142= | Silent (SNP) | VAF 109/360 reads (30%) | catalogued as rs758262178, COSV62349912; called by muse, mutect2, varscan2
- ADGRV1 | c.8766G>A p.V2922= | Silent (SNP) | VAF 33/195 reads (17%) | called by muse, mutect2, varscan2
- AEBP1 | c.517C>T p.L173= | Silent (SNP) | VAF 249/612 reads (41%) | catalogued as rs769637012, COSV56262333; called by muse, mutect2, varscan2
- AKAP6 | c.372C>T p.L124= | Silent (SNP) | VAF 65/247 reads (26%) | called by muse, mutect2, varscan2
- ALKBH4 | c.207C>T p.P69= | Silent (SNP) | VAF 266/553 reads (48%) | catalogued as COSV52962408; called by muse, mutect2, varscan2
- ANK3 | c.13092G>A p.T4364= (on ENST00000280772 / NM_001320874.2; = p.T988= on NM_001149.3) | Silent (SNP) | VAF 24/223 reads (11%) | catalogued as rs775425679, COSV55046749; called by muse, mutect2, varscan2
- ANK3 | c.2748C>T p.S916= (on ENST00000280772 / NM_001320874.2; = p.S50= on NM_001149.3) | Silent (SNP) | VAF 43/195 reads (22%) | called by muse, mutect2, varscan2
- ANKK1 | c.1722G>A p.L574= | Silent (SNP) | VAF 107/403 reads (27%) | catalogued as COSV58274619; called by muse, mutect2, varscan2
- ANO8 | c.1512C>T p.A504= | Silent (SNP) | VAF 154/565 reads (27%) | called by muse, mutect2, varscan2
- API5 | c.960C>T p.L320= | Silent (SNP) | VAF 56/227 reads (25%) | catalogued as rs1255044927; called by muse, mutect2, varscan2
- APOB | c.8307C>T p.F2769= | Silent (SNP) | VAF 111/415 reads (27%) | catalogued as COSV51947046; called by muse, mutect2, varscan2
- APOB | c.7095C>T p.A2365= | Silent (SNP) | VAF 86/316 reads (27%) | called by muse, mutect2, varscan2
- AREG | c.423G>A p.K141= | Silent (SNP) | VAF 75/312 reads (24%) | called by muse, mutect2, varscan2
- ARMC4 | c.2619G>A p.G873= | Silent (SNP) | VAF 16/135 reads (12%) | called by muse, mutect2, varscan2
- ASPM | c.6924C>T p.F2308= | Silent (SNP) | VAF 86/375 reads (23%) | catalogued as COSV54132973; called by muse, varscan2
- ATG9A | c.906C>T p.P302= | Silent (SNP) | VAF 131/461 reads (28%) | called by muse, mutect2, varscan2
- ATG9B | c.855G>A p.L285= | Silent (SNP) | VAF 230/541 reads (43%) | called by muse, mutect2, varscan2
- ATP13A5 | c.1935G>A p.Q645= | Silent (SNP) | VAF 65/259 reads (25%) | called by muse, mutect2, varscan2
- BAIAP3 | c.2586C>T p.H862= | Silent (SNP) | VAF 142/438 reads (32%) | catalogued as rs1296266873; called by muse, mutect2, varscan2
- BOD1 | c.426C>T p.N142= | Silent (SNP) | VAF 49/431 reads (11%) | called by muse, mutect2, varscan2
- BTBD18 | c.195G>T p.R65= | Silent (SNP) | VAF 123/391 reads (31%) | called by muse, mutect2, varscan2
- C7 | c.1470C>T p.V490= | Silent (SNP) | VAF 94/267 reads (35%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.150C>T p.A50= | Silent (SNP) | VAF 68/290 reads (23%) | called by muse, mutect2, varscan2
- CBX7 | c.610C>T p.L204= | Silent (SNP) | VAF 85/334 reads (25%) | called by muse, mutect2, varscan2
- CCN4 | c.495C>T p.L165= | Silent (SNP) | VAF 160/603 reads (27%) | catalogued as COSV51529822; called by muse, mutect2, varscan2
- CCNI2 | c.384G>A p.L128= | Silent (SNP) | VAF 132/271 reads (49%) | called by muse, mutect2, varscan2
- CDH23 | c.354G>A p.V118= | Silent (SNP) | VAF 106/264 reads (40%) | called by muse, mutect2, varscan2
- CDH6 | c.972C>T p.T324= | Silent (SNP) | VAF 100/248 reads (40%) | catalogued as rs1169361303, COSV54070484; called by muse, mutect2, varscan2
- CDT1 | c.546G>A p.P182= | Silent (SNP) | VAF 130/472 reads (28%) | catalogued as rs770311076; called by muse, mutect2, varscan2
- CELSR1 | c.546T>C p.R182= | Silent (SNP) | VAF 129/368 reads (35%) | called by muse, mutect2, varscan2
- CLK2 | c.1359C>T p.F453= (on ENST00000368361 / NM_001294339.2; = p.F452= on NM_003993.4) | Silent (SNP) | VAF 110/671 reads (16%) | catalogued as rs778696939, COSV56945606; called by muse, mutect2, varscan2
- CLP1 | c.105G>A p.L35= | Silent (SNP) | VAF 35/443 reads (8%) | called by muse, mutect2
- CRISP2 | c.294C>T p.L98= | Silent (SNP) | VAF 86/286 reads (30%) | called by muse, mutect2, varscan2
- CRNN | c.369G>A p.V123= | Silent (SNP) | VAF 131/729 reads (18%) | catalogued as rs1262488178; called by muse, mutect2, varscan2
- CRY2 | c.1035C>T p.A345= | Silent (SNP) | VAF 144/529 reads (27%) | called by muse, mutect2, varscan2
- CSF1 | c.429C>T p.L143= | Silent (SNP) | VAF 84/273 reads (31%) | catalogued as rs779131069; called by muse, mutect2, varscan2
- CSMD1 | c.5817C>T p.S1939= (on ENST00000520002; = p.S1938= on NM_033225.6) | Silent (SNP) | VAF 71/426 reads (17%) | catalogued as rs761086058; called by muse, mutect2, varscan2
- CST9 | c.312G>A p.R104= | Silent (SNP) | VAF 106/366 reads (29%) | called by muse, mutect2, varscan2
- CTPS1 | c.1605G>A p.K535= | Silent (SNP) | VAF 14/447 reads (3%) | called by muse, mutect2
- CX3CL1 | c.321C>T p.I107= | Silent (SNP) | VAF 109/419 reads (26%) | catalogued as rs750328440; called by muse, mutect2, varscan2
- CYP26B1 | c.1446C>T p.P482= | Silent (SNP) | VAF 96/332 reads (29%) | catalogued as rs368847380; called by muse, mutect2, varscan2
- CYP2C8 | c.504C>T p.F168= | Silent (SNP) | VAF 21/176 reads (12%) | catalogued as COSV64878701; called by muse, mutect2, varscan2
- DACT1 | c.2172C>T p.S724= | Silent (SNP) | VAF 139/437 reads (32%) | catalogued as rs767912076, COSV60023680; called by muse, mutect2, varscan2
- DBX1 | c.732C>T p.L244= | Silent (SNP) | VAF 87/283 reads (31%) | called by muse, mutect2, varscan2
- DCDC1 | c.4686G>A p.Q1562= (on ENST00000597505 / NM_001367979.1; = p.Q669= on NM_020869.3) | Silent (SNP) | VAF 59/223 reads (26%) | called by muse, mutect2, varscan2
- DIRAS2 | c.486C>T p.F162= | Silent (SNP) | VAF 107/226 reads (47%) | catalogued as rs74888015, COSV65370628; called by muse, mutect2, varscan2
- DNAH11 | c.3099C>T p.T1033= | Silent (SNP) | VAF 163/404 reads (40%) | called by muse, mutect2
- DNAH5 | c.2241G>A p.R747= | Silent (SNP) | VAF 33/192 reads (17%) | catalogued as rs866717001, COSV54205015; called by muse, mutect2, varscan2
- DNAH6 | c.10581G>A p.V3527= | Silent (SNP) | VAF 109/383 reads (28%) | called by muse, mutect2, varscan2
- DVL1 | c.417C>T p.S139= | Silent (SNP) | VAF 90/360 reads (25%) | catalogued as rs142599773; called by muse, mutect2, varscan2
- EMB | c.489G>A p.G163= | Silent (SNP) | VAF 28/109 reads (26%) | called by muse, mutect2, varscan2
- EPC1 | c.996C>T p.I332= | Silent (SNP) | VAF 61/183 reads (33%) | called by muse, mutect2, varscan2
- ERICH3 | c.1077G>A p.V359= | Silent (SNP) | VAF 122/390 reads (31%) | catalogued as rs866447707, COSV58613676; called by muse, mutect2, varscan2
- FAM107A | c.384G>A p.R128= | Silent (SNP) | VAF 100/380 reads (26%) | catalogued as rs1559472656; called by muse, mutect2, varscan2
- FAM171A1 | c.1971C>T p.S657= | Silent (SNP) | VAF 40/384 reads (10%) | catalogued as rs908450471; called by muse, mutect2, varscan2
- FAM71E2 | c.2136G>A p.S712= | Silent (SNP) | VAF 100/364 reads (27%) | catalogued as rs1409443191; called by muse, mutect2, varscan2
- FAT3 | c.2847C>T p.L949= | Silent (SNP) | VAF 69/246 reads (28%) | called by muse, mutect2, varscan2
- FBXO40 | c.2088C>T p.V696= | Silent (SNP) | VAF 87/293 reads (30%) | catalogued as COSV57522603, COSV57523820; called by muse, mutect2, varscan2
- FMO2 | c.318C>T p.F106= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as rs1353339848; called by muse, mutect2, varscan2
- FOXM1 | c.1233C>T p.A411= | Silent (SNP) | VAF 135/410 reads (33%) | called by muse, mutect2, varscan2
- FRAS1 | c.369C>T p.V123= | Silent (SNP) | VAF 96/392 reads (24%) | called by muse, mutect2, varscan2
- GLP1R | c.832C>T p.L278= | Silent (SNP) | VAF 88/353 reads (25%) | catalogued as rs1366151858; called by muse, mutect2, varscan2
- GOLGA3 | c.4419G>C p.P1473= | Silent (SNP) | VAF 153/534 reads (29%) | catalogued as rs777921874, COSV52645356; called by muse, mutect2, varscan2
- GPR3 | c.456G>A p.R152= | Silent (SNP) | VAF 160/506 reads (32%) | called by muse, mutect2, varscan2
- GPR55 | c.489G>A p.V163= | Silent (SNP) | VAF 118/424 reads (28%) | catalogued as COSV67408051; called by muse, mutect2
- GRIA1 | c.1335G>A p.E445= | Silent (SNP) | VAF 130/271 reads (48%) | called by muse, mutect2, varscan2
- HDAC9 | c.2967G>A p.P989= | Silent (SNP) | VAF 82/257 reads (32%) | catalogued as rs934474709, COSV67770591; called by muse, mutect2, varscan2
- HS3ST3B1 | c.1065G>A p.R355= | Silent (SNP) | VAF 70/353 reads (20%) | catalogued as rs1414023899, COSV62906779; called by muse, mutect2, varscan2
- HSD17B6 | c.120C>T p.G40= | Silent (SNP) | VAF 122/398 reads (31%) | called by muse, mutect2, varscan2
- HTR2C | c.1026C>T p.N342= | Silent (SNP) | VAF 130/222 reads (59%) | called by muse, varscan2
- HYDIN | c.13851G>A p.L4617= | Silent (SNP) | VAF 65/494 reads (13%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.1530G>A p.L510= | Silent (SNP) | VAF 76/305 reads (25%) | catalogued as rs1282390623; called by muse, mutect2, varscan2
- IGHG1 | c.99C>T p.F33= | Silent (SNP) | VAF 121/506 reads (24%) | called by muse, mutect2, varscan2
- IGKV1-8 | c.273C>T p.F91= | Silent (SNP) | VAF 127/417 reads (30%) | called by muse, mutect2, varscan2
- IGSF21 | c.375C>T p.T125= | Silent (SNP) | VAF 99/387 reads (26%) | called by muse, mutect2, varscan2
- KCNA3 | c.1179G>C p.A393= | Silent (SNP) | VAF 98/388 reads (25%) | catalogued as COSV63901540; called by muse, mutect2, varscan2
- KCNT2 | c.183G>A p.R61= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as rs1215812960, COSV54090482; called by muse, mutect2, varscan2
- KCTD1 | c.651C>T p.I217= | Silent (SNP) | VAF 81/287 reads (28%) | catalogued as rs1347122662, COSV100517546; ClinVar: likely benign; called by muse, mutect2, varscan2
- KDM4B | c.1200C>T p.L400= | Silent (SNP) | VAF 124/530 reads (23%) | called by muse, varscan2
- KDM4B | c.1201C>T p.L401= | Silent (SNP) | VAF 128/538 reads (24%) | called by muse, varscan2
- KDM6B | c.2580C>T p.S860= | Silent (SNP) | VAF 140/597 reads (23%) | catalogued as rs755078709; called by muse, mutect2, varscan2
- KIR3DL1 | c.273G>A p.G91= | Silent (SNP) | VAF 143/268 reads (53%) | catalogued as rs756823195; called by muse, mutect2, varscan2
- KLHDC7A | c.822C>T p.F274= | Silent (SNP) | VAF 135/379 reads (36%) | catalogued as rs865970083, COSV68770042; called by muse, mutect2, varscan2
- KLHL25 | c.225C>T p.F75= | Silent (SNP) | VAF 118/408 reads (29%) | called by muse, mutect2, varscan2
- KRTAP5-10 | c.270C>T p.S90= | Silent (SNP) | VAF 28/223 reads (13%) | catalogued as rs773635289; called by muse, mutect2, varscan2
- L3MBTL1 | c.2310C>T p.V770= (on ENST00000418998 / NM_001377303.1; = p.V680= on NM_015478.7) | Silent (SNP) | VAF 102/333 reads (31%) | catalogued as rs776666405, COSV64229546; called by muse, mutect2, varscan2
- LETMD1 | c.18G>A p.V6= | Silent (SNP) | VAF 77/315 reads (24%) | catalogued as rs1254636468; called by muse, mutect2, varscan2
- LRRC3B | c.513C>T p.I171= | Silent (SNP) | VAF 110/389 reads (28%) | called by muse, mutect2, varscan2
- LRRC43 | c.369C>T p.F123= | Silent (SNP) | VAF 94/350 reads (27%) | catalogued as COSV60292767; called by muse, mutect2, varscan2
- LRRD1 | c.1017C>T p.T339= | Silent (SNP) | VAF 111/260 reads (43%) | called by muse, mutect2, varscan2
- MAP4K2 | c.636C>T p.P212= | Silent (SNP) | VAF 107/344 reads (31%) | catalogued as rs776288662; called by muse, mutect2, varscan2
- MAP7D1 | c.1815G>A p.E605= | Silent (SNP) | VAF 158/573 reads (28%) | called by muse, mutect2, varscan2
- MBIP | c.165C>T p.I55= | Silent (SNP) | VAF 50/248 reads (20%) | catalogued as rs1263040914; called by muse, varscan2
- MBOAT7 | c.574C>T p.L192= | Silent (SNP) | VAF 192/665 reads (29%) | called by muse, mutect2, varscan2
- MGAM2 | c.1149C>T p.V383= | Silent (SNP) | VAF 151/333 reads (45%) | catalogued as rs559141932; called by muse, mutect2, varscan2
- MOV10L1 | c.402C>T p.I134= | Silent (SNP) | VAF 128/422 reads (30%) | called by muse, mutect2, varscan2
- MSX2 | c.702C>T p.S234= | Silent (SNP) | VAF 83/402 reads (21%) | called by muse, mutect2, varscan2
- MUC17 | c.4746C>T p.T1582= | Silent (SNP) | VAF 122/538 reads (23%) | catalogued as rs1263785572; called by muse, mutect2, varscan2
- MUC17 | c.10873C>T p.L3625= | Silent (SNP) | VAF 117/538 reads (22%) | called by muse, mutect2, varscan2
- MUC5AC | c.1230C>T p.S410= | Silent (SNP) | VAF 72/249 reads (29%) | catalogued as rs1330893079, COSV62253315; called by muse, mutect2, varscan2
- MYH11 | c.5556G>A p.K1852= | Silent (SNP) | VAF 132/413 reads (32%) | called by muse, mutect2, varscan2
- MYH15 | c.1941G>A p.E647= | Silent (SNP) | VAF 49/174 reads (28%) | called by muse, mutect2, varscan2
- MYO7A | c.6342C>T p.F2114= | Silent (SNP) | VAF 78/281 reads (28%) | catalogued as rs751923355; called by muse, mutect2, varscan2
- NEXMIF | c.4524G>A p.E1508= | Silent (SNP) | VAF 62/128 reads (48%) | called by muse, mutect2, varscan2
- NHS | c.4797G>A p.R1599= | Silent (SNP) | VAF 101/181 reads (56%) | called by muse, mutect2, varscan2
- NLRP2 | c.1182G>A p.L394= | Silent (SNP) | VAF 239/769 reads (31%) | called by muse, mutect2, varscan2
- NLRP5 | c.120C>T p.F40= | Silent (SNP) | VAF 94/300 reads (31%) | catalogued as rs369527947; called by muse, mutect2, varscan2
- NMRAL1 | c.231C>T p.I77= | Silent (SNP) | VAF 127/456 reads (28%) | catalogued as rs756900384, COSV52060023; called by muse, mutect2, varscan2
- NRXN1 | c.243G>A p.L81= | Silent (SNP) | VAF 124/493 reads (25%) | catalogued as COSV68009507, COSV68017424; called by muse, mutect2, varscan2
- NTSR2 | c.186C>T p.A62= | Silent (SNP) | VAF 155/490 reads (32%) | catalogued as rs572448656; called by muse, mutect2
- OR10AG1 | c.594C>T p.I198= | Silent (SNP) | VAF 103/352 reads (29%) | catalogued as COSV56631498; called by muse, mutect2, varscan2
- OR10X1 | c.918G>A p.R306= | Silent (SNP) | VAF 72/435 reads (17%) | catalogued as COSV63767828; called by muse, mutect2, varscan2
- OR11H2 | c.198C>T p.F66= (on ENST00000556246; = p.F77= on NM_001197287.1) | Silent (SNP) | VAF 89/296 reads (30%) | called by muse, mutect2, varscan2
- OR1Q1 | c.321C>T p.F107= | Silent (SNP) | VAF 69/211 reads (33%) | catalogued as rs771925852, COSV52917895; called by muse, mutect2, varscan2
- OR2T3 | c.906C>T p.V302= | Silent (SNP) | VAF 111/983 reads (11%) | called by muse, mutect2, varscan2
- OR3A2 | c.639C>T p.F213= | Silent (SNP) | VAF 135/503 reads (27%) | catalogued as COSV68694956; called by muse, mutect2, varscan2
- OR5M1 | c.93C>T p.F31= | Silent (SNP) | VAF 114/371 reads (31%) | catalogued as COSV73202416; called by muse, mutect2, varscan2
- OR7A17 | c.606A>G p.A202= | Silent (SNP) | VAF 100/317 reads (32%) | called by muse, mutect2, varscan2
- OR9A4 | c.75C>T p.I25= | Silent (SNP) | VAF 177/390 reads (45%) | catalogued as COSV71885665, COSV71886080; called by muse, mutect2, varscan2
- OR9G4 | c.735C>T p.L245= | Silent (SNP) | VAF 110/412 reads (27%) | called by muse, mutect2, varscan2
- OSBP2 | c.6G>A p.G2= | Silent (SNP) | VAF 49/205 reads (24%) | called by muse, mutect2, varscan2
- OSBPL7 | c.1083C>T p.T361= | Silent (SNP) | VAF 89/353 reads (25%) | called by muse, mutect2, varscan2
- OTOL1 | c.711G>A p.E237= | Silent (SNP) | VAF 55/224 reads (25%) | called by muse, mutect2, varscan2
- OTP | c.357G>A p.L119= | Silent (SNP) | VAF 69/354 reads (19%) | called by muse, mutect2, varscan2
- OTX2 | c.81C>T p.P27= | Silent (SNP) | VAF 76/262 reads (29%) | catalogued as CD051777, COSV59767941; called by muse, mutect2, varscan2
- PATE2 | c.201G>A p.R67= | Silent (SNP) | VAF 57/190 reads (30%) | catalogued as COSV100653493; called by muse, mutect2, varscan2
- PDE1A | c.1167C>T p.F389= | Silent (SNP) | VAF 58/192 reads (30%) | catalogued as rs149666537, COSV59514499, COSV59524484; called by muse, mutect2, varscan2
- PDE6C | c.1542C>T p.F514= | Silent (SNP) | VAF 100/280 reads (36%) | catalogued as COSV65116832; called by muse, mutect2, varscan2
- PGLYRP2 | c.990C>T p.S330= | Silent (SNP) | VAF 110/379 reads (29%) | catalogued as rs566477628, COSV52993882; called by muse, mutect2, varscan2
- PIK3C2A | c.3123A>G p.R1041= | Silent (SNP) | VAF 126/368 reads (34%) | called by muse, mutect2, varscan2
- PIWIL1 | c.2337C>T p.I779= | Silent (SNP) | VAF 77/278 reads (28%) | catalogued as rs1181198037, COSV55344928; called by muse, mutect2, varscan2
- PPFIA3 | c.766C>T p.L256= | Silent (SNP) | VAF 146/513 reads (28%) | catalogued as rs1267337579; called by muse, mutect2, varscan2
- PPP2R1A | c.1515C>T p.I505= | Silent (SNP) | VAF 79/271 reads (29%) | catalogued as COSV100436434; called by muse, mutect2, varscan2
- PRUNE2 | c.5160G>A p.L1720= | Silent (SNP) | VAF 70/208 reads (34%) | called by muse, mutect2, varscan2
- PYGM | c.981C>T p.F327= | Silent (SNP) | VAF 69/267 reads (26%) | catalogued as rs146289842; ClinVar: likely benign; called by muse, mutect2, varscan2
- QRSL1 | c.1576C>T p.L526= | Silent (SNP) | VAF 51/122 reads (42%) | called by muse, mutect2, varscan2
- RALYL | c.618C>T p.I206= | Silent (SNP) | VAF 79/288 reads (27%) | catalogued as rs1184680411; called by muse, mutect2, varscan2
- RBM14 | c.279G>A p.Q93= | Silent (SNP) | VAF 117/378 reads (31%) | catalogued as rs1239613080; called by muse, mutect2, varscan2
- RYR1 | c.14481C>T p.I4827= | Silent (SNP) | VAF 87/343 reads (25%) | catalogued as rs1232814586; called by muse, mutect2, varscan2
- S1PR4 | c.927C>T p.F309= | Silent (SNP) | VAF 159/541 reads (29%) | called by muse, mutect2, varscan2
- SCN7A | c.4149C>T p.I1383= | Silent (SNP) | VAF 113/385 reads (29%) | called by muse, mutect2, varscan2
- SEC14L4 | c.843G>A p.T281= | Silent (SNP) | VAF 142/466 reads (30%) | catalogued as rs760802294, COSV55399798; called by muse, varscan2
- SEZ6L | c.2343G>A p.G781= | Silent (SNP) | VAF 99/405 reads (24%) | called by muse, mutect2, varscan2
- SH3PXD2B | c.93C>T p.V31= | Silent (SNP) | VAF 82/202 reads (41%) | called by muse, mutect2, varscan2
- SHROOM3 | c.3093C>T p.I1031= | Silent (SNP) | VAF 158/512 reads (31%) | called by muse, mutect2, varscan2
- SIGLEC11 | c.1378C>T p.L460= | Silent (SNP) | VAF 121/413 reads (29%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.4779C>T p.P1593= | Silent (SNP) | VAF 135/512 reads (26%) | called by muse, mutect2, varscan2
- SLC22A10 | c.741C>T p.I247= | Silent (SNP) | VAF 158/491 reads (32%) | called by muse, mutect2, varscan2
- SLC25A12 | c.1842C>T p.P614= | Silent (SNP) | VAF 62/204 reads (30%) | catalogued as rs551188942; called by muse, mutect2, varscan2
- SLC2A9 | c.1182C>T p.F394= | Silent (SNP) | VAF 118/351 reads (34%) | catalogued as COSV53322166; called by muse, mutect2, varscan2
- SLC35C2 | c.639C>T p.F213= | Silent (SNP) | VAF 112/323 reads (35%) | called by muse, mutect2, varscan2
- SLC35E3 | c.342C>T p.I114= | Silent (SNP) | VAF 144/434 reads (33%) | catalogued as rs1026250035; called by muse, mutect2, varscan2
- SLC6A17 | c.801C>T p.F267= | Silent (SNP) | VAF 100/368 reads (27%) | catalogued as rs1470657987, COSV100521198; called by muse, varscan2
- SLC7A10 | c.387C>T p.I129= | Silent (SNP) | VAF 106/320 reads (33%) | catalogued as rs369501411; called by muse, mutect2, varscan2
- SLC8A3 | c.1830G>A p.R610= | Silent (SNP) | VAF 54/240 reads (23%) | catalogued as COSV53688599; called by muse, mutect2, varscan2
- SLFN5 | c.1245T>C p.S415= | Silent (SNP) | VAF 68/304 reads (22%) | called by muse, mutect2, varscan2
- SNX17 | c.222G>A p.Q74= | Silent (SNP) | VAF 96/353 reads (27%) | called by muse, mutect2, varscan2
- SPATS1 | c.162G>A p.L54= | Silent (SNP) | VAF 100/285 reads (35%) | called by muse, mutect2, varscan2
- SRRM2 | c.99G>A p.R33= | Silent (SNP) | VAF 117/450 reads (26%) | catalogued as rs538727516; called by muse, mutect2, varscan2
- STAB1 | c.975C>T p.S325= | Silent (SNP) | VAF 100/373 reads (27%) | catalogued as rs1196872337; called by muse, mutect2, varscan2
- SUSD4 | c.435C>T p.I145= | Silent (SNP) | VAF 98/326 reads (30%) | called by muse, mutect2, varscan2
- SZT2 | c.8133C>T p.F2711= (on ENST00000634258 / NM_001365999.1; = p.F2654= on NM_015284.4) | Silent (SNP) | VAF 64/234 reads (27%) | called by muse, mutect2, varscan2
- TBC1D30 | c.1716G>A p.G572= (on ENST00000542120; = p.G409= on NM_015279.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 96/368 reads (26%) | catalogued as rs1360941574; called by muse, mutect2, varscan2
- TFEB | c.1249C>T p.L417= | Silent (SNP) | VAF 289/469 reads (62%) | called by muse, mutect2, varscan2
- TMEM178B | c.588C>T p.D196= | Silent (SNP) | VAF 101/552 reads (18%) | called by muse, mutect2, varscan2
- TMEM233 | c.162C>T p.I54= | Silent (SNP) | VAF 97/317 reads (31%) | catalogued as rs1264297946, COSV101460123; called by muse, mutect2, varscan2
- TMEM62 | c.1113C>T p.P371= | Silent (SNP) | VAF 97/382 reads (25%) | catalogued as COSV53042381; called by muse, mutect2, varscan2
- TMPRSS11F | c.321A>G p.R107= | Silent (SNP) | VAF 46/172 reads (27%) | called by muse, mutect2, varscan2
- TNFSF8 | c.291G>A p.K97= | Silent (SNP) | VAF 71/183 reads (39%) | called by muse, mutect2, varscan2
- TPO | c.1488G>A p.T496= | Silent (SNP) | VAF 164/565 reads (29%) | catalogued as rs758020153, COSV100219517, COSV61101552; called by muse, mutect2, varscan2
- TSEN54 | c.906C>T p.S302= | Silent (SNP) | VAF 131/497 reads (26%) | catalogued as rs774219646; called by muse, mutect2, varscan2
- TSPOAP1 | c.1401G>A p.E467= | Silent (SNP) | VAF 121/398 reads (30%) | catalogued as rs1228777617; called by muse, mutect2, varscan2
- TTN | c.22287G>A p.K7429= (on ENST00000591111; = p.K6502= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/300 reads (21%) | catalogued as COSV59887641; called by muse, mutect2, varscan2
- TTN | c.14856G>A p.L4952= (on ENST00000591111; = p.L4025= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 96/273 reads (35%) | catalogued as rs1291505269, COSV60418398; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP29 | c.550C>T p.L184= | Silent (SNP) | VAF 100/311 reads (32%) | catalogued as rs147668479; called by muse, mutect2, varscan2
- VPS13B | c.8103A>T p.T2701= | Silent (SNP) | VAF 117/325 reads (36%) | called by muse, mutect2, varscan2
- VPS37C | c.297C>T p.T99= | Silent (SNP) | VAF 90/323 reads (28%) | called by muse, mutect2, varscan2
- WBP4 | c.1065C>T p.V355= | Silent (SNP) | VAF 84/294 reads (29%) | catalogued as rs754147527; called by muse, mutect2, varscan2
- WFDC10B | c.36C>T p.L12= | Silent (SNP) | VAF 110/438 reads (25%) | catalogued as rs1362758629, COSV57913232; called by muse, mutect2
- WNT7A | c.408G>A p.E136= | Silent (SNP) | VAF 185/536 reads (35%) | catalogued as rs759663787, COSV53201190; called by muse, mutect2, varscan2
- XKR3 | c.471C>T p.F157= | Silent (SNP) | VAF 139/446 reads (31%) | catalogued as COSV58886594; called by muse, mutect2, varscan2
- ZNF385D | c.114C>T p.P38= | Silent (SNP) | VAF 90/334 reads (27%) | catalogued as COSV55747346; called by muse, mutect2, varscan2
- ZNF454 | c.405C>T p.I135= | Silent (SNP) | VAF 115/302 reads (38%) | catalogued as rs1276335760, COSV100194910, COSV60767011, COSV60769487; called by muse, mutect2, varscan2
- ZNF621 | c.870T>A p.P290= | Silent (SNP) | VAF 100/341 reads (29%) | called by muse, mutect2, varscan2
- ZSWIM1 | c.282C>T p.T94= | Silent (SNP) | VAF 55/348 reads (16%) | called by muse, mutect2, varscan2
- ZZEF1 | c.6733C>T p.L2245= | Silent (SNP) | VAF 90/305 reads (30%) | catalogued as rs528156783; called by muse, mutect2, varscan2
- CRY2 | chr11:45847448 C>T | 5'Flank (SNP) | VAF 130/381 reads (34%) | catalogued as rs945593447, COSV69889479; called by muse, mutect2, varscan2
- DCHS2 | n.3708C>T | RNA (SNP) | VAF 94/292 reads (32%) | catalogued as COSV61768345; called by muse, mutect2, varscan2
- EEF1D | c.-7-2720C>T | Intron (SNP) | VAF 148/453 reads (33%) | catalogued as rs370356009; called by muse, mutect2, varscan2
- FAM182B | n.427G>A | RNA (SNP) | VAF 60/214 reads (28%) | called by muse, varscan2
- FGFR3 | c.*1412G>A | 3'UTR (SNP) | VAF 152/484 reads (31%) | catalogued as rs548817695, COSV53407950; called by muse, mutect2, varscan2
- KCNH5 | c.2020-4253C>T | Intron (SNP) | VAF 111/333 reads (33%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+27611T>C | Intron (SNP) | VAF 45/153 reads (29%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+28925G>A | Intron (SNP) | VAF 72/260 reads (28%) | catalogued as rs1172621891; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-8133C>T | Intron (SNP) | VAF 61/210 reads (29%) | called by muse, mutect2, varscan2
- LIMCH1 | c.936-7636G>A | Intron (SNP) | VAF 102/382 reads (27%) | called by muse, mutect2, varscan2
- MAPK10 | c.*105G>A | 3'UTR (SNP) | VAF 89/282 reads (32%) | called by muse, mutect2, varscan2
- REXO1L1P | chr8:85663129 G>A | 5'Flank (SNP) | VAF 14/452 reads (3%) | called by muse, mutect2
- RNF216 | c.202-87C>T | Intron (SNP) | VAF 109/510 reads (21%) | called by muse, mutect2, varscan2
- SLC25A47 | c.-1C>T | 5'UTR (SNP) | VAF 90/292 reads (31%) | called by muse, mutect2, varscan2
- SPTBN4 | c.5915+89G>A | Intron (SNP) | VAF 42/172 reads (24%) | catalogued as rs766944172, COSV58945086; called by muse, mutect2, varscan2
- TTN | c.34264+5507C>T | Intron (SNP) | VAF 65/262 reads (25%) | catalogued as rs1437532734, COSV100625159; called by muse, mutect2, varscan2
- WDR64 | c.*151G>A | 3'UTR (SNP) | VAF 97/393 reads (25%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+3126C>T | Intron (SNP) | VAF 335/695 reads (48%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+3127C>T | Intron (SNP) | VAF 308/652 reads (47%) | catalogued as rs1168815508; called by muse, varscan2
